MMRF case MMRF_2442 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7a085dbc-6737-4923-955a-6c7166a35864

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.7 years (22,918 days); ISS stage: I; Days to last known disease status: 716 days (2.0 years); Days to last follow up: 716 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 190 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 36 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 36 days; Days to treatment end: 190 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 221 days; Days to treatment end: 221 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 224 days; Days to treatment end: 225 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 406 days (1.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 1): M Protein 2.52 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 27.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.29 mg/dL; Immunoglobulin G 35.9 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.89 µg/mL; Hemoglobin 7.19 mmol/L; Leukocytes 3.54 ×10⁹/L; Absolute Neutrophil 1.46 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 8.6 g/dL; Glucose 5.83 mmol/L.
- Day 94 (ECOG 0): M Protein 0.5 g/dL; Immunoglobulin G 6.47 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 6.29 ×10⁹/L; Absolute Neutrophil 3.62 ×10⁹/L; Platelets 114 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 4.35 mmol/L.
- Day 220 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Immunoglobulin G 6.37 g/L; Immunoglobulin A 0.75 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 1.86 µg/mL; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 51.4 ×10⁹/L; Absolute Neutrophil 42.3 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.43 mmol/L; Albumin 46 g/L; Total Protein 6.5 g/dL; Glucose 6.11 mmol/L.
- Day 256 (ECOG 0): Hemoglobin 6.76 mmol/L; Leukocytes 4.41 ×10⁹/L; Absolute Neutrophil 1.63 ×10⁹/L; Platelets 334 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 5.39 mmol/L.
- Day 343: M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Immunoglobulin G 6.82 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.79 µg/mL; Hemoglobin 8.31 mmol/L; Leukocytes 5.31 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 7.1 mmol/L.
- Day 430: M Protein 0.4 g/dL; Immunoglobulin G 7.34 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.42 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.98 ×10⁹/L; Absolute Neutrophil 1.83 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 4.35 mmol/L.
- Day 522: M Protein 0.5 g/dL; Immunoglobulin G 8.25 g/L; Immunoglobulin A 1.08 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 8 mmol/L; Leukocytes 3.18 ×10⁹/L; Absolute Neutrophil 1.33 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 6.44 mmol/L.
- Day 638 (ECOG 0): M Protein 0.6 g/dL; Immunoglobulin G 9.53 g/L; Immunoglobulin A 1.54 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 3.31 ×10⁹/L; Absolute Neutrophil 1.42 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.48 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 5.61 mmol/L.
- Day 716: M Protein 0.6 g/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 1.66 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 0.97 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 4.84 mmol/L.

Other clinical attributes
- Day -4: Weight: 71 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2442_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_2442_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
